Gene-level copy-number profile of tumor specimen ALCH-B1JS-TTP1-A from ALCHEMIST case ALCH-B1JS, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 63.1 years (23,062 days).
Specimen ALCH-B1JS-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b9b33722-0254-4153-8485-7c443479884f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1JS-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,231 have no estimate.
https://portal.gdc.cancer.gov/files/0b3e5854-e75d-4e6b-bf14-f849d687e016

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 32; copy number 1: 1,678; copy number 2: 52,682; copy number 3: 3,962; copy number 4: 17; copy number 5: 4; copy number 6: 7; copy number 7: 1; copy number 8: 1; copy number 9: 1; copy number 10: 3; copy number 11: 1; copy number 15: 3.

Homozygous deletions (total copy number 0; autosomes only): 32 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,331,280–1,349,418, 3 genes: TAS1R3, DVL1, MIR6808.
- chr1:148,772,640–148,796,325, 2 genes: SEC22B3P, AC245389.1.
- chr2:87,194,786–87,194,859, 1 gene (within-gene range 0–1): MIR4771-1.
- chr3:53,797,764–53,798,019, 1 gene (within-gene range 0–2): AC012467.1.
- chr6:134,074,123–134,121,433, 2 genes: AL449363.2, HMGA1P7.
- chr8:41,645,177–41,650,817, 1 gene: NKX6-3.
- chr8:46,028,804–46,028,892, 1 gene: AC118650.1.
- chr8:102,528,740–102,539,943, 2 genes: AP002852.1, RNU6-1224P.
- chr9:61,190,003–61,453,030, 7 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P.
- chr14:63,543,569–63,544,664, 1 gene: AL136038.3.
- chr16:3,024,027–3,027,755, 1 gene (within-gene range 0–2): THOC6.
- chr17:36,377,531–36,439,566, 3 genes (within-gene range 0–1): TBC1D3H, RNU6-1192P, TBC1D3F.
- chr17:60,135,762–60,140,081, 1 gene: AC025048.1.
- chr17:79,707,176–79,712,317, 2 genes: MIR4739, LINC02078.
- chr19:1,000,419–1,009,732, 1 gene (within-gene range 0–2): GRIN3B.
- chr19:1,010,221–1,010,907, 1 gene (within-gene range 0–2): AC004528.2.
- chr21:14,064,325–14,070,986, 2 genes (within-gene range 0–2): ANKRD20A18P, RNA5SP488.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 21 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,352,689–1,361,777, 1 gene, copy number 8: MXRA8.
- chr7:56,955,785–56,955,864, 1 gene, copy number 11: MIR4283-1.
- chr9:62,532,337–62,534,724, 2 genes, copy number 5: BX005266.2, BX005266.1.
- chr9:62,601,226–62,711,398, 6 genes, copy number 6–15: RBPJP7, RAB28P2, BX005266.3, ATP5F1AP7, SDR42E1P3, FKBP4P7.
- chr13:112,313,467–112,321,758, 1 gene, copy number 5: LINC01043.
- chr14:104,857,792–104,858,836, 1 gene, copy number 5: AL583810.1.
- chr17:18,415,728–18,425,097, 1 gene, copy number 10 (within-gene range 2–10): KRT17P5.
- chr17:18,426,861–18,442,895, 2 genes, copy number 10: KRT17P2, KRT16P1.
- chr19:58,543,299–58,555,105, 4 genes, copy number 6: RN7SL525P, TRIM28, MIR6807, CHMP2A.
- chr21:44,107,373–44,210,114, 2 genes, copy number 7–9 (within-gene range 2–9): PWP2, GATD3A.

Autosomal genes at a single copy (total copy number 1): 1,537. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
